Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GR-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Uterus, cervix, total abdominal hysterectomy with bilateral salpingo-oophorectomy

Location of tumor: endometrium

Histologic type: endometrioid adenocarcinoma

Histologic grade (FIGO): 3 (architectural grade 3, nuclear grade 3) (A16)

Extent of invasion:

Myometrial invasion: Inner half

Depth: 5 mm Wall thickness: 1.5

cm Percent: 33% (A16, deeper level)

Serosal involvement: absent

Lower uterine segment involvement: absent

Cervical involvement: absent

Adnexal involvement (see below): absent

Other sites: N/A

Cervical/vaginal margin and distance: widely free of tumor

Lymphovascular Space Invasion: present (A5)

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 25

Other Pathologic findings: none

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

AJCC Pathologic stage: pT1a pN0 pMX

1CD-0-3

Adenocarcinoma, endometrioid, NOS

8380/3

Site: Endometrium C54.1

2/1/11
fw

HIIPAA Discrepancy		X

[page 2 of 5]
FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:

- Atrophic ovary, no tumor seen

Ovary, left, oophorectomy:

- Atrophic ovary, no tumor seen

Fallopian tube, right, salpingectomy:

- No tumor seen

Fallopian tube, left, salpingectomy:

- No tumor seen

B: Lymph node, left pelvic, removal

- Eight lymph nodes, no tumor seen (0/8)

C: Lymph node, right pelvic, removal

- Eight lymph nodes, no tumor seen (0/8)

D: Lymph node, left periaortic, removal

- Three lymph nodes, no tumor seen (0/3)

E: Lymph node, right periaortic removal

- Six lymph nodes, no tumor seen (0/6)

Clinical History:

The patient is with a history of grade 3 uterine cancer.

Gross Description:

Specimen A is received in an appropriately labeled container.

Adnexa: Bilateral ovaries and tubes present with specimen.

Weight: 450.09 grams

Shape: Grapefruit shaped

Dimensions:

height: 11 cm

anterior to posterior width: 9.5 cm

breadth at fundus: 10.0 cm

Serosa: Tan/pink, smooth and glistening

Cervix:

length of endocervical canal: 3.5 cm

[page 3 of 5]
ectocervix: White/pink with focal areas of hemorrhage.

endocervix: Yellow/tan and trabeculated. There was a small 0.5 x 0.5 x 0.3 cm polypoid mass on the anterior endocervix.

Endomyometrium:

length of endometrial cavity: 6.0 cm

width of endometrial cavity at fundus: 6.5 cm

tumor findings:

dimensions: 8.9 cm anterior to posterior x 7.5 cm medial to lateral x 5.6 cm from cephalad to caudad.

appearance: Large tan/white fungating mass

location and extent: Appears to invade both anterior and posterior endometrial cavities.

myometrial invasion: Gross invasion is identified to the inner one-half on the anterior side and posterior side.

thickness of myometrial wall at deepest gross invasion: 1.5 cm

other findings or comments: None

Adnexa:

Right ovary:

dimensions: 2.4 x 1.6 x 1.4 cm

external surface: Pink/tan, convoluted

cut surface: Tan/yellow variegated without masses.

Right fallopian tube:

dimensions: 5.5 x 0.5 cm

other findings: Fimbriated end present

Left ovary:

dimensions: 2.6 x 1.8 x 1.3 cm

external surface: Tan/pink, convoluted without masses.

cut surface: Yellow/tan variegated with focal areas of hemorrhage.

Left fallopian tube:

dimensions: 5.4 x 0.5 cm

other findings: Fimbriated end present

Lymph nodes: Per blocks B-E

Other comments: None

Digital photograph taken: No

Tissue submitted for special investigations:

Block Summary:

A1 - anterior cervix

A2 - posterior cervix

A3 - anterior lower uterine segment

A4 - posterior uterine segment

A5-A6 - anterior mid corpus from superficial to deep

A7 - anterior upper corpus/fundus

A8 - additional section anterior upper corpus/fundus

A9-A10 - posterior upper corpus/fundus, bisected

[page 4 of 5]
A11-A12 - posterior mid corpus, bisected
A14-A15 - posterior upper corpus, bisected
A16-A17 - additional section anterior upper corpus/fundus
A18 - right ovary and right fallopian tube
A19 - left ovary and left fallopian tube

(A13 block not submitted)

Specimen B is received in an appropriately labeled container, additionally labeled "L pelvic lymph node" and is a 4.8 x 3.0 x 1.8 cm aggregate of tan/yellow fibroadipose tissue with lymph node candidates.

Block Summary:

B1 - one lymph node candidate, bisected
B2 - three lymph node candidates
B3 - one lymph node candidate, bisected
B4 - four lymph node candidates
Fibroadipose tissue remains.

Specimen C is received in an appropriately labeled container additionally labeled "R pelvic lymph node" and is a 4.7 x 4.7 x 1.6 cm aggregate of tan/yellow fibroadipose tissue with lymph node candidates.

Block Summary:

C1-C2 - one lymph node candidate, bisected
C3 - four lymph node candidates
C4 - two lymph node candidates
C5 - one lymph node candidate, bisected
C6 - one lymph node candidate, bisected
Fibroadipose tissue remains.

Specimen D is received in an appropriately labeled container, additionally labeled "L periaortic LN" and is a 3.2 x 1.6 x 0.9 cm aggregate of fibroadipose tissue and lymph node candidates.

Block Summary:

D1 - one lymph node candidate, bisected
D2 - additional lymph node candidate with remaining fibroadipose tissue, NTR

Specimen E is received in an appropriately labeled container, additionally labeled "R periaortic LN" and is a 2.5 x 2.1 x 0.7 cm aggregate of yellow/tan fibroadipose tissue and lymph node candidates.

Block Summary:

E1 - one lymph node candidate, bisected
E2 - four lymph node candidates
Fibroadipose tissue

Grossing Pathologist:

[page 5 of 5]
Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Procedures/Addenda:

Addendum

Addendum

Immunostains for ER and PR are performed on a representative block of endometrial tumor. The tumor is ER positive (1-2+, 85%) and PR positive (2+, 65%).

For cases in which immunostains are performed, the following applies: Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the manufacturer. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 2896396d-105a-4e43-89a6-94c8d741d37e (TCGA-EY-A1GR.1C53C957-1A0A-46AF-A53B-0287683D52F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).